Somatic mutation profile of tumor specimen C3L-00991-01 (aliquot CPT0122990009) from CPTAC case C3L-00991, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 45.7 years (16,703 days).
Specimen C3L-00991-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) faa756d8-458d-4647-aece-3030d7b21a4a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00991-31 (Blood Derived Normal), aliquot CPT0124740002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/00901f2f-afc8-499f-b990-39d81fd66227

The open-access MAF lists 57 somatic variants for this specimen: 47 protein-altering or splice-affecting, 6 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 6, Nonsense Mutation 4, Frame Shift Del 4, Splice Site 2, 3'UTR 2, Nonstop Mutation 1, 5'Flank 1, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.444del p.F148Lfs*11 | Frame Shift Del (DEL) | VAF 48/408 reads (12%) | catalogued as rs869025653, CM982009; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ACVR1B | c.1465C>T p.R489C | Missense Mutation (SNP) | VAF 17/343 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752443171, COSV57777503; called by muse, mutect2
- ALOX12 | c.1043G>A p.R348Q | Missense Mutation (SNP) | VAF 26/438 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs1297300834, COSV52348905; called by muse, mutect2
- BAP1 | c.661G>T p.E221* | Nonsense Mutation (SNP) | VAF 48/475 reads (10%) | catalogued as COSV56238699, COSV56238962; called by muse, mutect2, varscan2
- CCDC105 | c.208C>T p.P70S | Missense Mutation (SNP) | VAF 34/244 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.629); catalogued as COSV52963569; called by muse, mutect2, varscan2
- CDK5RAP2 | c.4540G>A p.E1514K | Missense Mutation (SNP) | VAF 54/505 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.065); catalogued as rs1329397628, COSV100575462; called by muse, mutect2, varscan2
- CHAF1B | c.66G>T p.Q22H | Missense Mutation (SNP) | VAF 22/256 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs765367431; called by muse, mutect2
- EDIL3 | c.584G>A p.R195H | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56884291; called by muse, mutect2
- FRMD7 | c.1556C>T p.P519L | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs762283064, COSV53748457; called by muse, mutect2, varscan2
- GSTM3 | c.544T>A p.F182I | Missense Mutation (SNP) | VAF 16/270 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV99860135; called by muse, mutect2
- KIAA0319 | c.1111G>T p.E371* | Nonsense Mutation (SNP) | VAF 22/254 reads (9%) | catalogued as rs1448858067, COSV100985767; called by muse, mutect2
- MUC16 | c.20708C>T p.S6903F | Missense Mutation (SNP) | VAF 47/312 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.813); catalogued as COSV67475581; called by muse, mutect2, varscan2
- MVB12B | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 34/361 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as rs1265205569; called by muse, mutect2
- PAK1IP1 | c.66G>C p.E22D | Missense Mutation (SNP) | VAF 31/365 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs772493979; called by muse, mutect2
- PHF14 | c.514G>A p.A172T | Missense Mutation (SNP) | VAF 16/236 reads (7%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0); catalogued as rs781174027, COSV68854252; called by muse, mutect2
- PISD | c.1096C>T p.R366C (on ENST00000439502 / NM_001326412.1; = p.R332C on NM_014338.3) | Missense Mutation (SNP) | VAF 25/393 reads (6%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.892); catalogued as rs749834707; called by muse, mutect2
- PITX2 | c.40C>T p.Q14* | Nonsense Mutation (SNP) | VAF 44/588 reads (7%) | catalogued as COSV100721759; called by muse, mutect2
- RERE | c.4369G>A p.D1457N | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs764757593; called by muse, mutect2, varscan2
- SHROOM2 | c.2603G>T p.R868L | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV66605360; called by muse, mutect2, varscan2
- SP140 | c.1516G>A p.G506S | Missense Mutation (SNP) | VAF 9/115 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs982905819; called by muse, mutect2
- TRABD2B | c.1472C>T p.S491L | Missense Mutation (SNP) | VAF 26/160 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); catalogued as rs903758988; called by muse, mutect2, varscan2
- USP16 | c.206C>G p.P69R | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100537785; called by muse, varscan2
- VANGL2 | c.203G>A p.W68* | Nonsense Mutation (SNP) | VAF 7/58 reads (12%) | catalogued as COSV63604478; called by muse, mutect2, varscan2
- VSIG10L | c.683G>A p.R228Q | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs903050041; called by muse, mutect2, varscan2
- ABCF3 | c.1351G>A p.A451T | Missense Mutation (SNP) | VAF 40/428 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ADGRL2 | c.2072A>T p.K691I (on ENST00000370717 / NM_001366005.1; = p.K678I on NM_012302.4) | Missense Mutation (SNP) | VAF 37/273 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- AKR1B10 | c.802G>A p.A268T | Missense Mutation (SNP) | VAF 30/280 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARID4B | c.2178A>T p.Q726H | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); called by muse, mutect2
- CTTNBP2 | c.4990T>G p.*1664Eext*9 | Nonstop Mutation (SNP) | VAF 14/119 reads (12%) | called by muse, mutect2, varscan2
- DMRT2 | c.98C>T p.T33M | Missense Mutation (SNP) | VAF 38/310 reads (12%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DMXL1 | c.6787del p.M2263Wfs*14 | Frame Shift Del (DEL) | VAF 13/122 reads (11%) | called by mutect2, pindel, varscan2
- ESPN | c.2325+1G>C p.X775_splice | Splice Site (SNP) | VAF 6/109 reads (6%) | called by muse, mutect2
- FAM155A | c.1334G>C p.G445A | Missense Mutation (SNP) | VAF 19/148 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- FN1 | c.5140C>G p.L1714V | Missense Mutation (SNP) | VAF 64/474 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.441); called by muse, mutect2, varscan2
- LOXL2 | c.1331A>G p.Y444C | Missense Mutation (SNP) | VAF 16/226 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.838); called by muse, mutect2
- LRP5 | c.580A>T p.I194F | Missense Mutation (SNP) | VAF 76/578 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MTMR7 | c.1750G>C p.G584R | Missense Mutation (SNP) | VAF 49/407 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- NSMCE3 | c.81del p.A29Lfs*59 | Frame Shift Del (DEL) | VAF 46/410 reads (11%) | called by mutect2, pindel, varscan2
- PARG | c.2020del p.E674Rfs*22 | Frame Shift Del (DEL) | VAF 24/192 reads (13%) | called by mutect2, varscan2
- PRPF8 | c.5460G>T p.K1820N | Missense Mutation (SNP) | VAF 105/827 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RNF212 | c.647G>T p.C216F (on ENST00000433731 / NM_001366918.1; = p.V198= on NM_194439.4) | Missense Mutation (SNP) | VAF 28/306 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.635); called by muse, mutect2
- SERPINF1 | c.463G>A p.V155M | Missense Mutation (SNP) | VAF 76/759 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- SYNE2 | c.19334-3C>T | Splice Region (SNP) | VAF 42/357 reads (12%) | called by muse, mutect2, varscan2
- SYNGR3 | c.224G>A p.G75D | Missense Mutation (SNP) | VAF 44/396 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM176A | c.70C>A p.H24N | Missense Mutation (SNP) | VAF 72/309 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- YTHDC1 | c.1960-1G>C p.X654_splice (on ENST00000344157 / NM_001031732.4; = p.X636_splice on NM_133370.4) | Splice Site (SNP) | VAF 20/169 reads (12%) | called by muse, mutect2, varscan2
- ZNF117 | c.260T>A p.V87E | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- AMIGO2 | c.582G>A p.L194= | Silent (SNP) | VAF 30/261 reads (11%) | called by muse, mutect2, varscan2
- BMPR1B | c.363A>T p.G121= | Silent (SNP) | VAF 19/187 reads (10%) | catalogued as rs780913868; called by muse, mutect2, varscan2
- CFAP74 | c.12C>T p.D4= | Silent (SNP) | VAF 28/230 reads (12%) | catalogued as rs199801677, COSV54567291; called by muse, varscan2
- LLGL1 | c.2730C>T p.S910= | Silent (SNP) | VAF 38/261 reads (15%) | catalogued as rs752194023; called by muse, mutect2, varscan2
- PTCHD3 | c.1596G>A p.T532= | Silent (SNP) | VAF 16/127 reads (13%) | catalogued as rs554598344; called by muse, mutect2, varscan2
- ZNF239 | c.633G>A p.Q211= | Silent (SNP) | VAF 35/296 reads (12%) | called by muse, mutect2, varscan2
- DHCR7 | c.964-76G>A | Intron (SNP) | VAF 14/106 reads (13%) | catalogued as rs923905452; called by muse, mutect2, varscan2
- NDRG4 | c.*83T>G | 3'UTR (SNP) | VAF 28/358 reads (8%) | called by muse, mutect2
- RNU6-104P | chr8:43300524 C>T | 5'Flank (SNP) | VAF 16/161 reads (10%) | catalogued as rs1440701127; called by mutect2, varscan2
- VAPB | c.*6159C>G | 3'UTR (SNP) | VAF 58/538 reads (11%) | called by muse, mutect2, varscan2
